Gene-level copy-number profile of tumor specimen ALCH-B1UI-TTP1-A from ALCHEMIST case ALCH-B1UI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Mixed invasive mucinous and non-mucinous adenocarcinoma; Age at diagnosis: 63.8 years (23,285 days).
Specimen ALCH-B1UI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0d95a87f-2977-4c62-8b47-bba655ba157a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1UI-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,238 have no estimate.
https://portal.gdc.cancer.gov/files/778fee81-5517-464b-84b3-75beb3e256c5

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 76; copy number 1: 17; copy number 2: 11,793; copy number 3: 3,855; copy number 4: 42,139; copy number 5: 424; copy number 6: 64; copy number 7: 3; copy number 8: 4; copy number 9: 4; copy number 10: 1; copy number 13: 3; copy number 16: 1; copy number 25: 1.

Homozygous deletions (total copy number 0; autosomes only): 74 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,231,266–21,441,316, 16 genes: IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1.
- chr9:21,455,484–21,456,049, 1 gene (within-gene range 0–1): IFNWP19.
- chr9:21,638,285–23,898,054, 30 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1, AL365204.2.
- chr9:27,245,680–29,826,711, 21 genes: LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.1, AL353684.1, AL354676.1, ME2P1.
- chr15:34,343,315–34,357,737, 1 gene: NUTM1.
- chr19:17,207,138–17,208,010, 1 gene (within-gene range 0–3): AC020913.2.
- chr19:50,797,704–50,804,929, 4 genes (within-gene range 0–3): C19orf48, SNORD88B, SNORD88A, SNORD88C.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 8 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:39,886,861–39,892,895, 3 genes, copy number 9: RN7SL763P, SNORA70, CR769767.1.
- chr9:39,983,821–39,984,401, 1 gene, copy number 9: RPL7AP49.
- chr9:40,121,962–40,122,540, 1 gene, copy number 16: CDRT15P14.
- chr9:61,581,813–61,642,494, 3 genes, copy number 13: AL935212.3, FAM242D, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 10. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
